Somatic mutation profile of tumor specimen TCGA-BJ-A3F0-01A (aliquot TCGA-BJ-A3F0-01A-11D-A202-08) from TCGA case TCGA-BJ-A3F0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 64.5 years (23,545 days).
Specimen TCGA-BJ-A3F0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66e43231-0a34-48e2-a226-be273f1953d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A3F0-10A (Blood Derived Normal), aliquot TCGA-BJ-A3F0-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d146e7e-fa74-4ca5-b0f0-cff1bf09176c

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs137854533, COSV55670877, COSV55673870; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.1516A>G p.K506E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1468014295, COSV50140240; called by muse, mutect2, varscan2
- CRY1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs1034031760, COSV50488977; called by muse, mutect2
- DOCK5 | c.3289C>T p.H1097Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV52409172; called by muse, mutect2, varscan2
- TIPARP | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV55814255; called by mutect2, varscan2
- TG | c.4847_4853dup p.S1619Hfs*12 | Frame Shift Ins (INS) | VAF 24/104 reads (23%) | called by mutect2, varscan2
- KIAA0895L | c.159C>T p.V53= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs764259245, COSV51783899; called by muse, mutect2, varscan2
- NPAS2 | c.396C>T p.F132= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV59555696, COSV59561244; called by muse, mutect2, varscan2
- RAI14 | c.2703C>T p.L901= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV54301721; called by muse, mutect2, varscan2
